TCGA case TCGA-BR-8680 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ab76544e-df6a-4b05-9317-054812474d4c

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Tubular adenocarcinoma: ICD-O-3 morphology code: 8211/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 45.5 years (16,637 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 972 days (2.7 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 10.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Epirubicin + Eribulin Mesylate + Oxaliplatin; Days to treatment start: 39 days; Days to treatment end: 150 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Methylprednisolone; Days to treatment start: 39 days; Days to treatment end: 150 days; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 24 days; Disease response: Tumor Free.
- Days to follow up: 481 days (1.3 years); Disease response: Tumor Free.
- Days to follow up: 972 days (2.7 years); Disease response: Tumor Free.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-8680-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 2; Shortest dimension: 0.4.
  Slide TCGA-BR-8680-01A-01-TS1: Section location: Top; Percent tumor cells: 78; Percent tumor nuclei: 75; Percent normal cells: 6; Percent necrosis: 15; Percent stromal cells: 1; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 5.
  Slide TCGA-BR-8680-01A-01-BS1: Section location: Bottom; Percent tumor cells: 68; Percent tumor nuclei: 65; Percent normal cells: 20; Percent necrosis: 10; Percent stromal cells: 2; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BR-8680-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-8680-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Tubular Type; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Cancer procurement city: Hanoi; History reflux disease indicator: No; History barretts esophageal indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Halaven.
- Drug treatment 4: Pharmaceutical therapy drug name: Medrol.
- Follow-up form 1: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 972 days; disease-specific survival: no event (censored), 972 days; progression-free interval: no event (censored), 972 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-8680-01A-11D-2390-01): tumor purity 0.68, ploidy 2, whole-genome doublings 0.
